Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017981-03A.1 (aliquot TARGET-15-SJMPAL017981-03A.1-01D) from TARGET case TARGET-15-SJMPAL017981, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.5 years (184 days).
Specimen TARGET-15-SJMPAL017981-03A.1: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63a41b61-bc75-4205-98be-bb944e54ada3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017981-10A (Blood Derived Normal), aliquot TARGET-15-SJMPAL017981-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71c6f105-9478-4293-82cb-9fb26f0e4449

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 46/297 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 59/273 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- COPB1 | c.2305G>T p.V769L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV51450214; called by mutect2, varscan2
- HTR1A | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100109024, COSV60499947, COSV60500527; called by muse, mutect2
- MYH9 | c.5194G>T p.A1732S | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.089); catalogued as rs1050130268, COSV99338910; called by muse, mutect2
- SLCO3A1 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as COSV59231265; called by muse, mutect2, varscan2
- WASH6P | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as rs772507094; called by muse, mutect2
- MCM3 | c.596G>T p.G199V (on ENST00000229854 / NM_001366374.2; = p.G189V on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TNRC18 | c.7747G>A p.G2583R | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.726); called by muse, varscan2
- SRRM2 | c.7734-132C>A | Intron (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2, varscan2
